Somatic mutation profile of tumor specimen TCGA-37-A5EM-01A (aliquot TCGA-37-A5EM-01A-21D-A27K-08) from TCGA case TCGA-37-A5EM, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage II; Age at diagnosis: 49.3 years (18,011 days).
Specimen TCGA-37-A5EM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 90f1c41e-425f-4a83-889e-01b90c672c10.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-37-A5EM-10A (Blood Derived Normal), aliquot TCGA-37-A5EM-10A-01D-A27N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ad07cc50-be52-46cc-9351-039721a71d5d

The open-access MAF lists 384 somatic variants for this specimen: 272 protein-altering or splice-affecting, 102 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 233, Silent 102, Nonsense Mutation 12, Frame Shift Del 11, Splice Region 6, Splice Site 6, RNA 5, Intron 3, Frame Shift Ins 2, 5'Flank 2, In Frame Ins 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACACB | c.4094G>T p.R1365L | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100622180; called by muse, mutect2, varscan2
- ACCS | c.1213A>T p.S405C | Missense Mutation (SNP) | VAF 43/130 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.84); catalogued as COSV99772614; called by muse, mutect2, varscan2
- ADAMTS17 | c.2422G>A p.G808S | Missense Mutation (SNP) | VAF 29/226 reads (13%) | SIFT tolerated (0.44); PolyPhen benign (0.009); catalogued as rs375971368; called by muse, mutect2, varscan2
- ADGRF5 | c.2438T>C p.V813A | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV51934569, COSV99344710; called by muse, mutect2, varscan2
- ADGRV1 | c.7316G>T p.C2439F | Missense Mutation (SNP) | VAF 23/39 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101315350; called by muse, mutect2, varscan2
- ADTRP | c.600C>A p.S200R | Missense Mutation (SNP) | VAF 78/1333 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.711); catalogued as COSV99994946; called by muse, mutect2
- AFDN | c.1579G>T p.G527* | Nonsense Mutation (SNP) | VAF 9/34 reads (26%) | catalogued as COSV100652331; called by muse, mutect2
- AGAP1 | c.340G>C p.D114H | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100363459; called by muse, mutect2, varscan2
- AKAP13 | c.3329A>G p.H1110R | Missense Mutation (SNP) | VAF 22/114 reads (19%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.079); catalogued as rs1387993966, COSV100772913; called by muse, mutect2, varscan2
- AKAP8L | c.1048G>T p.G350W | Missense Mutation (SNP) | VAF 28/99 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs751057330, COSV101275700, COSV68474092; called by muse, mutect2, varscan2
- ANAPC1 | c.2344G>A p.G782R | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV100594472; called by muse, mutect2, varscan2
- ANK2 | c.10473G>T p.R3491S | Missense Mutation (SNP) | VAF 38/93 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.536); catalogued as COSV99999040; called by muse, mutect2, varscan2
- ANO5 | c.1751G>A p.G584D | Missense Mutation (SNP) | VAF 30/105 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100201299; called by muse, mutect2, varscan2
- ARAP2 | c.3924C>G p.D1308E | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT tolerated (0.47); PolyPhen benign (0.056); catalogued as COSV100393997; called by muse, mutect2, varscan2
- ARFGEF1 | c.5291A>T p.Y1764F | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99137945; called by muse, mutect2, varscan2
- ARMC4 | c.2353C>G p.Q785E | Missense Mutation (SNP) | VAF 20/109 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.81); catalogued as COSV100536160; called by muse, mutect2, varscan2
- ARNTL | c.1235C>G p.S412C (on ENST00000403290 / NM_001297719.2; = p.S411C on NM_001178.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.85); catalogued as COSV100724506; called by muse, mutect2, varscan2
- ASB8 | c.396G>C p.E132D | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs1565926429, COSV100402209; called by muse, mutect2, varscan2
- ATP6V0A2 | c.2165C>T p.A722V | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs766224435, COSV57749420; called by muse, mutect2, varscan2
- BAIAP2L1 | c.494A>G p.E165G | Missense Mutation (SNP) | VAF 38/80 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99133557; called by muse, mutect2, varscan2
- BANK1 | c.1592C>A p.P531Q | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.81); PolyPhen benign (0.005); catalogued as COSV100535671; called by muse, mutect2, varscan2
- BARD1 | c.802G>C p.E268Q | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV53613980, COSV99637696, COSV99637785; called by muse, mutect2, varscan2
- BEND7 | c.505G>T p.V169L | Missense Mutation (SNP) | VAF 48/132 reads (36%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.009); catalogued as COSV100346276; called by muse, mutect2, varscan2
- BEND7 | c.106C>T p.P36S | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.998); catalogued as COSV61989743, COSV61990290; called by muse, mutect2, varscan2
- BPIFB6 | c.1172C>T p.S391L | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.771); catalogued as rs774420213, COSV62754115, COSV62754524; called by muse, mutect2, varscan2
- BRCA1 | c.5398C>G p.L1800V | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated (0.44); PolyPhen benign (0.014); catalogued as COSV100523159; called by muse, mutect2, varscan2
- BRINP3 | c.1895G>A p.R632H | Missense Mutation (SNP) | VAF 23/414 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs751255099, COSV66528308; called by muse, mutect2
- C1QB | c.676G>C p.D226H | Missense Mutation (SNP) | VAF 34/131 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV100152677; called by muse, mutect2, varscan2
- C6 | c.2591A>T p.Y864F | Missense Mutation (SNP) | VAF 92/355 reads (26%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.726); catalogued as COSV99666290; called by muse, mutect2, varscan2
- CA11 | c.610C>A p.R204S | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.66); catalogued as COSV50033049, COSV99320478; called by muse, mutect2, varscan2
- CA14 | c.502G>A p.E168K | Missense Mutation (SNP) | VAF 74/182 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.339); catalogued as COSV52528634; called by muse, varscan2
- CAD | c.1957A>G p.I653V | Missense Mutation (SNP) | VAF 25/101 reads (25%) | SIFT tolerated (0.61); PolyPhen benign (0.017); catalogued as COSV99254271; called by muse, mutect2, varscan2
- CAPN15 | c.2237G>A p.G746D | Missense Mutation (SNP) | VAF 36/100 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99562099; called by muse, mutect2, varscan2
- CCAR1 | c.1367G>A p.S456N | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.968); catalogued as rs1255613107, COSV99770496; called by muse, mutect2, varscan2
- CD2AP | c.1235G>T p.R412L | Missense Mutation (SNP) | VAF 70/261 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.097); catalogued as COSV100830262; called by muse, mutect2, varscan2
- CDCP2 | c.94G>T p.G32C | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1342573107, COSV100313263; called by muse, mutect2, varscan2
- CDH15 | c.2320G>T p.A774S | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.051); catalogued as rs890942238, COSV99227894, COSV99228724; called by muse, mutect2, varscan2
- CDON | c.3292A>T p.T1098S | Missense Mutation (SNP) | VAF 10/13 reads (77%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); catalogued as COSV99700417; called by muse, mutect2
- CFHR4 | c.1273G>T p.G425* (on ENST00000367416 / NM_001201551.2; = p.G179* on NM_006684.5) | Nonsense Mutation (SNP) | VAF 37/91 reads (41%) | catalogued as rs770918628, COSV99259324; called by muse, mutect2, varscan2
- CFHR4 | c.1701G>T p.R567S (on ENST00000367416 / NM_001201551.2; = p.R321S on NM_006684.5) | Missense Mutation (SNP) | VAF 94/207 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.306); catalogued as COSV52234536, COSV99259327; called by muse, mutect2, varscan2
- CHRM2 | c.1347G>C p.K449N | Missense Mutation (SNP) | VAF 18/149 reads (12%) | SIFT tolerated (0.31); PolyPhen benign (0.082); catalogued as COSV100280556, COSV57773131, COSV57785401; called by muse, mutect2, varscan2
- CNKSR1 | c.614A>T p.D205V | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT tolerated (0.17); PolyPhen benign (0.036); catalogued as COSV100836654; called by muse, varscan2
- COL5A1 | c.3782G>T p.G1261V | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100879342; called by muse, mutect2
- CORO7-PAM16 | c.3012T>G p.F1004L | Missense Mutation (SNP) | VAF 40/88 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.164); catalogued as COSV99267252; called by muse, mutect2, varscan2
- CPAMD8 | c.1600G>T p.E534* (on ENST00000651564; = p.E487* on NM_015692.5) | Nonsense Mutation (SNP) | VAF 41/163 reads (25%) | catalogued as COSV99358865; called by muse, mutect2, varscan2
- CRACD | c.2255G>C p.G752A | Missense Mutation (SNP) | VAF 51/131 reads (39%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV51729871, COSV99948402; called by muse, mutect2, varscan2
- CSMD2 | c.4202G>T p.W1401L | Missense Mutation (SNP) | VAF 31/139 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.158); catalogued as COSV99584835; called by muse, mutect2, varscan2
- CSMD3 | c.2362C>T p.L788F (on ENST00000297405 / NM_001363185.1; = p.L684F on NM_052900.3) | Missense Mutation (SNP) | VAF 77/135 reads (57%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.606); catalogued as COSV52188167; called by muse, mutect2, varscan2
- CYBB | c.631C>G p.L211V | Missense Mutation (SNP) | VAF 44/71 reads (62%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.999); catalogued as COSV101059670; called by muse, mutect2, varscan2
- DBH | c.1435-2A>C p.X479_splice | Splice Site (SNP) | VAF 16/81 reads (20%) | catalogued as COSV101256776; called by muse, mutect2, varscan2
- DCAF11 | c.1529G>A p.W510* | Nonsense Mutation (SNP) | VAF 23/46 reads (50%) | catalogued as COSV100386548; called by muse, mutect2, varscan2
- DCC | c.1419-1G>A p.X473_splice | Splice Site (SNP) | VAF 19/67 reads (28%) | catalogued as COSV100497579; called by muse, mutect2, varscan2
- DCD | c.291A>T p.G97= | Splice Region (SNP) | VAF 4/10 reads (40%) | catalogued as COSV99513893; called by muse, mutect2
- DHX57 | c.455G>A p.G152E | Missense Mutation (SNP) | VAF 4/66 reads (6%) | SIFT tolerated (0.83); PolyPhen benign (0.001); catalogued as rs1212408090, COSV99768973, COSV99769970; called by muse, mutect2
- DIPK1C | c.1231C>A p.L411M | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated, low confidence (0.16); PolyPhen possibly damaging (0.564); catalogued as COSV100679726; called by muse, mutect2
- DNMT3L | c.632G>T p.S211I | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT tolerated (0.69); PolyPhen benign (0.319); catalogued as COSV99533122; called by muse, mutect2, varscan2
- EDEM3 | c.2589G>C p.Q863H | Missense Mutation (SNP) | VAF 32/62 reads (52%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.135); catalogued as COSV100544799; called by muse, mutect2, varscan2
- ELMO1 | c.414G>C p.E138D | Missense Mutation (SNP) | VAF 51/141 reads (36%) | SIFT tolerated (0.92); PolyPhen benign (0.005); catalogued as COSV100162795; called by muse, mutect2, varscan2
- EPHA8 | c.1829A>C p.Y610S | Missense Mutation (SNP) | VAF 61/202 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99384046; called by muse, mutect2, varscan2
- ESF1 | c.901G>T p.D301Y | Missense Mutation (SNP) | VAF 28/127 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99176245; called by muse, mutect2, varscan2
- F5 | c.4009A>C p.T1337P | Missense Mutation (SNP) | VAF 174/544 reads (32%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.133); catalogued as COSV100888833; called by muse, mutect2, varscan2
- FAAH2 | c.1414G>T p.A472S | Missense Mutation (SNP) | VAF 42/74 reads (57%) | SIFT tolerated (0.53); PolyPhen benign (0.023); catalogued as COSV66508327; called by muse, mutect2, varscan2
- FAM160A2 | c.2087T>G p.L696* (on ENST00000449352 / NM_001098794.2; = p.L710* on NM_032127.4) | Nonsense Mutation (SNP) | VAF 15/93 reads (16%) | catalogued as COSV99791619; called by muse, mutect2, varscan2
- FBXO40 | c.1483G>T p.V495F | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.66); catalogued as COSV100572905; called by muse, mutect2, varscan2
- FCGBP | c.4334A>T p.E1445V | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT tolerated (0.28); PolyPhen benign (0.026); catalogued as COSV99660451; called by muse, mutect2, varscan2
- FCHO1 | c.295G>T p.V99F | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.572); catalogued as COSV99405742; called by muse, mutect2, varscan2
- FCRL1 | c.901A>G p.R301G | Missense Mutation (SNP) | VAF 50/103 reads (49%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV100839695; called by muse, mutect2, varscan2
- FNDC1 | c.185C>A p.P62H | Missense Mutation (SNP) | VAF 49/185 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99794641; called by muse, mutect2, varscan2
- FRAS1 | c.673G>T p.G225C | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99347517; called by muse, mutect2, varscan2
- FUT5 | c.624G>T p.W208C | Missense Mutation (SNP) | VAF 35/110 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99398467; called by muse, mutect2, varscan2
- GALNT17 | c.134G>T p.R45L | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.194); catalogued as COSV100351848, COSV61161682; called by muse, mutect2, varscan2
- GAPVD1 | c.253G>T p.G85W | Missense Mutation (SNP) | VAF 47/145 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99782519; called by muse, mutect2, varscan2
- GAS2L1 | c.1502G>T p.S501I | Missense Mutation (SNP) | VAF 67/107 reads (63%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV99329352; called by muse, mutect2, varscan2
- GBX2 | c.589G>A p.E197K | Missense Mutation (SNP) | VAF 41/156 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.039); catalogued as rs924320246, COSV100103401; called by muse, mutect2, varscan2
- GEN1 | c.220A>G p.M74V | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.069); catalogued as COSV100437711; called by muse, mutect2, varscan2
- GLUD1 | c.1268T>C p.M423T | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.047); catalogued as COSV99517856; called by muse, mutect2, varscan2
- GNAL | c.770T>A p.L257Q (on ENST00000269162 / NM_001142339.3; = p.L334Q on NM_182978.4) | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99302934; called by muse, mutect2, varscan2
- GORASP2 | c.340C>T p.H114Y | Missense Mutation (SNP) | VAF 42/164 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1436955991, COSV99304400; called by muse, mutect2, varscan2
- GPR32 | c.1064G>T p.R355L | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.015); catalogued as COSV54514472, COSV99567043; called by muse, mutect2, varscan2
- GPR37 | c.1739G>A p.S580N | Missense Mutation (SNP) | VAF 9/185 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.039); catalogued as COSV100390458, COSV100391166, COSV58259746; called by muse, mutect2
- GRAMD1B | c.1481G>T p.S494I | Missense Mutation (SNP) | VAF 38/91 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.154); catalogued as COSV100454193; called by muse, mutect2, varscan2
- GRHL1 | c.1269G>A p.K423= | Splice Region (SNP) | VAF 70/268 reads (26%) | catalogued as COSV100257419; called by muse, mutect2, varscan2
- GRIP1 | c.2932G>T p.G978C (on ENST00000359742 / NM_001379345.1; = p.G926C on NM_021150.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 45/168 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV99667680; called by muse, mutect2, varscan2
- GRM3 | c.1975C>A p.L659M | Missense Mutation (SNP) | VAF 125/261 reads (48%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as rs377052357, COSV100862021; called by muse, mutect2, varscan2
- HCN1 | c.2535G>T p.M845I | Missense Mutation (SNP) | VAF 34/140 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.885); catalogued as COSV100297963; called by muse, mutect2, varscan2
- HELZ2 | c.3928C>T p.P1310S (on ENST00000467148 / NM_001037335.2; = p.P741S on NM_033405.3) | Missense Mutation (SNP) | VAF 21/101 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV71296742, COSV71296990; called by muse, mutect2, varscan2
- HERC2 | c.10931G>T p.R3644L | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.598); catalogued as COSV99870251; called by muse, mutect2, varscan2
- HERC4 | c.2528+2T>A p.X843_splice (on ENST00000395198 / NM_022079.3; = p.X835_splice on NM_015601.4 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 32/78 reads (41%) | catalogued as COSV99516424; called by muse, mutect2, varscan2
- HGFAC | c.1762G>A p.D588N | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.277); catalogued as rs754747260, COSV66976916; called by muse, mutect2, varscan2
- HNMT | c.874G>T p.A292S | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (0.73); PolyPhen benign (0.022); catalogued as rs758209010, COSV99698664; called by muse, mutect2, varscan2
- HS6ST3 | c.654C>G p.C218W | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100939904; called by muse, mutect2, varscan2
- HSPA6 | c.488C>A p.A163E | Missense Mutation (SNP) | VAF 18/135 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV100553814, COSV100553971, COSV59062196; called by muse, mutect2, varscan2
- HYDIN | c.15056G>A p.G5019E | Missense Mutation (SNP) | VAF 33/121 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101124811, COSV66642193; called by muse, mutect2, varscan2
- HYDIN | c.8075T>C p.F2692S | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV99991753; called by muse, mutect2, varscan2
- IFFO1 | c.193G>C p.A65P | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100350667, COSV100351288; called by muse, mutect2, varscan2
- IGDCC3 | c.554G>T p.R185M | Missense Mutation (SNP) | VAF 29/180 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100030548; called by muse, mutect2, varscan2
- IGHMBP2 | c.1886A>G p.Y629C | Missense Mutation (SNP) | VAF 77/326 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV99661690; called by muse, mutect2, varscan2
- IL17C | c.421C>A p.R141S | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.576); catalogued as COSV99733089; called by muse, mutect2, varscan2
- INVS | c.880C>T p.H294Y | Missense Mutation (SNP) | VAF 45/156 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99316927; called by muse, mutect2, varscan2
- IQUB | c.23A>T p.Y8F | Missense Mutation (SNP) | VAF 32/56 reads (57%) | SIFT tolerated, low confidence (0.9); PolyPhen benign (0); catalogued as rs1037801260, COSV100226660; called by muse, mutect2, varscan2
- ITGA1 | c.422T>C p.L141S | Missense Mutation (SNP) | VAF 41/118 reads (35%) | SIFT tolerated (0.55); PolyPhen benign (0.044); catalogued as COSV99250487; called by muse, mutect2, varscan2
- ITGAL | c.100C>G p.R34G | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.35); PolyPhen benign (0.015); catalogued as COSV100776004; called by muse, mutect2, varscan2
- ITIH2 | c.455C>A p.A152D | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV100623112; called by muse, mutect2, varscan2
- JARID2 | c.1812G>C p.E604D | Missense Mutation (SNP) | VAF 140/162 reads (86%) | SIFT tolerated (0.36); PolyPhen benign (0.104); catalogued as rs768843433, COSV100521141; called by muse, varscan2
- KCNH7 | c.241C>T p.Q81* | Nonsense Mutation (SNP) | VAF 17/44 reads (39%) | catalogued as COSV59788346; called by muse, mutect2, varscan2
- KIAA1586 | c.1171G>A p.G391S | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV100875267; called by muse, mutect2, varscan2
- KIFAP3 | c.543G>T p.R181S | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV100846664; called by muse, mutect2, varscan2
- KLHL40 | c.1205G>T p.R402L | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99825288; called by muse, mutect2, varscan2
- KMT2D | c.14189G>T p.W4730L | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV99976790; called by muse, mutect2, varscan2
- KRT6B | c.849A>T p.E283D | Missense Mutation (SNP) | VAF 21/108 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0.282); catalogued as COSV99360368; called by muse, mutect2, varscan2
- LMX1A | c.397G>T p.D133Y | Missense Mutation (SNP) | VAF 101/191 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99671479, COSV99671963; called by muse, mutect2, varscan2
- LRGUK | c.604C>T p.H202Y | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99603644; called by muse, mutect2, varscan2
- LRP1 | c.464C>T p.S155L | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.067); catalogued as rs777340776, COSV99674020; called by muse, mutect2, varscan2
- LRP2 | c.7925C>A p.T2642N | Missense Mutation (SNP) | VAF 62/188 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.133); catalogued as COSV99786067; called by muse, mutect2, varscan2
- MAGEC3 | c.731T>A p.V244E | Missense Mutation (SNP) | VAF 59/102 reads (58%) | SIFT deleterious (0.01); PolyPhen benign (0.387); catalogued as COSV100024705; called by muse, mutect2, varscan2
- MAN1A1 | c.1327-2A>T p.X443_splice | Splice Site (SNP) | VAF 16/45 reads (36%) | catalogued as COSV100870563; called by muse, mutect2, varscan2
- MANEA | c.814A>T p.I272F | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as COSV100721414; called by muse, mutect2, varscan2
- MARCHF1 | c.163-6C>T | Splice Region (SNP) | VAF 26/73 reads (36%) | catalogued as COSV99919704; called by muse, mutect2, varscan2
- MBD6 | c.1199C>G p.S400C | Missense Mutation (SNP) | VAF 14/127 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.258); catalogued as COSV63072961; called by muse, mutect2, varscan2
- MCM3AP | c.1948del p.E650Rfs*6 | Frame Shift Del (DEL) | VAF 15/50 reads (30%) | catalogued as COSV99387192; called by mutect2, pindel, varscan2
- MCPH1 | c.596A>G p.Q199R | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.022); catalogued as COSV60916074; called by muse, mutect2, varscan2
- MED15 | c.579G>C p.Q193H | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.991); catalogued as COSV99487260, COSV99487542; called by muse, varscan2
- MIER3 | c.95A>T p.D32V | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); catalogued as COSV100423499, COSV61229121; called by muse, mutect2, varscan2
- MLF1 | c.91A>G p.R31G | Missense Mutation (SNP) | VAF 35/137 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.909); catalogued as COSV100575931; called by muse, mutect2, varscan2
- MMAA | c.441A>G p.G147= | Splice Region (SNP) | VAF 31/77 reads (40%) | catalogued as COSV99849577; called by muse, mutect2, varscan2
- MORF4L1 | c.286del p.V96Ffs*33 (on ENST00000331268 / NM_206839.2; = p.V57Ffs*33 on NM_006791.4) | Frame Shift Del (DEL) | VAF 12/82 reads (15%) | catalogued as COSV58704151; called by mutect2, pindel, varscan2
- MRE11 | c.341G>C p.G114A | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.54); PolyPhen benign (0.012); catalogued as COSV100119377, COSV60581311; called by muse, mutect2, varscan2
- MTNR1B | c.470C>A p.T157N | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs986476523, COSV57067550, COSV57068028; called by muse, mutect2, varscan2
- MUC4 | c.14719G>A p.E4907K (on ENST00000463781 / NM_018406.7; = p.E671K on NM_004532.6) | Missense Mutation (SNP) | VAF 32/278 reads (12%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.001); catalogued as COSV100203232; called by muse, mutect2, varscan2
- MUC4 | c.2006C>A p.S669Y | Missense Mutation (SNP) | VAF 34/306 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.618); catalogued as COSV100638825, COSV62144301; called by muse, mutect2, varscan2
- MUC4 | c.746C>G p.S249C | Missense Mutation (SNP) | VAF 31/263 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.709); catalogued as COSV100638827; called by muse, mutect2, varscan2
- MUC4 | c.564C>G p.I188M | Missense Mutation (SNP) | VAF 81/515 reads (16%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.318); catalogued as COSV100638828; called by muse, mutect2, varscan2
- MYH3 | c.277A>T p.M93L | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as COSV99877593; called by muse, mutect2, varscan2
- MYO1A | c.247G>T p.V83L | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV100270465; called by muse, mutect2, varscan2
- MYO3A | c.3687A>T p.K1229N | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.015); catalogued as COSV99777829; called by muse, mutect2, varscan2
- NAV3 | c.3265G>C p.G1089R | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT tolerated (0.2); PolyPhen probably damaging (1); catalogued as COSV57066279, COSV99886100; called by muse, mutect2
- NDN | c.28G>T p.D10Y | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.005); catalogued as COSV100086167; called by muse, mutect2, varscan2
- NFKBIA | c.953G>C p.*318Sext*5 | Nonstop Mutation (SNP) | VAF 5/136 reads (4%) | catalogued as COSV99394857; called by muse, mutect2
- NID2 | c.103G>A p.E35K | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.06); catalogued as COSV99355801; called by muse, mutect2, varscan2
- NLRP4 | c.2192T>C p.V731A | Missense Mutation (SNP) | VAF 56/110 reads (51%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV56717108; called by muse, mutect2, varscan2
- NXNL1 | c.206G>A p.R69Q | Missense Mutation (SNP) | VAF 38/126 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as rs757310322, COSV100111923; called by muse, mutect2, varscan2
- OR11A1 | c.695G>T p.G232V | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.115); catalogued as COSV101010664; called by muse, mutect2, varscan2
- OR11H1 | c.616C>G p.L206V | Missense Mutation (SNP) | VAF 37/138 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.155); catalogued as rs918655495, COSV99421518; called by muse, mutect2, varscan2
- OR13C4 | c.425T>A p.V142E | Missense Mutation (SNP) | VAF 49/164 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.213); catalogued as COSV52926029, COSV99469907; called by muse, mutect2, varscan2
- OR1C1 | c.811G>C p.D271H | Missense Mutation (SNP) | VAF 27/135 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101376168, COSV68715818; called by muse, mutect2, varscan2
- OR4A16 | c.469C>A p.Q157K | Missense Mutation (SNP) | VAF 36/118 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.479); catalogued as COSV100124958; called by muse, mutect2, varscan2
- OR51A7 | c.254T>A p.F85Y | Missense Mutation (SNP) | VAF 38/134 reads (28%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.982); catalogued as COSV100834570; called by muse, mutect2
- OR51I2 | c.168T>G p.H56Q | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs772350779, COSV100413257; called by muse, mutect2, varscan2
- OR5D14 | c.416C>A p.S139* | Nonsense Mutation (SNP) | VAF 27/86 reads (31%) | catalogued as COSV100162038, COSV59457922; called by muse, mutect2, varscan2
- OR6N2 | c.37G>T p.V13L | Missense Mutation (SNP) | VAF 29/121 reads (24%) | SIFT tolerated (0.25); PolyPhen benign (0.041); catalogued as COSV100209923, COSV59413482; called by muse, mutect2, varscan2
- OR8B8 | c.554T>C p.L185P | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.766); catalogued as COSV100044771; called by muse, mutect2, varscan2
- OR8H3 | c.859C>T p.P287S | Missense Mutation (SNP) | VAF 27/128 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV57908455; called by muse, mutect2, varscan2
- OTOF | c.1206G>T p.G402= | Splice Region (SNP) | VAF 14/34 reads (41%) | catalogued as rs1233499839, COSV99716249, COSV99718640; called by muse, mutect2, varscan2
- OTOGL | c.6694A>G p.T2232A (on ENST00000547103; = p.T2223A on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 43/141 reads (30%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as COSV54016747; called by muse, mutect2, varscan2
- PAPPA2 | c.4971del p.S1658Qfs*3 | Frame Shift Del (DEL) | VAF 44/109 reads (40%) | catalogued as COSV62799933; called by mutect2, pindel, varscan2
- PAQR6 | c.968C>A p.A323D (on ENST00000292291 / NM_001272108.2; = p.P241T on NM_024897.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT tolerated (0.32); PolyPhen benign (0.034); catalogued as COSV99430655; called by muse, mutect2, varscan2
- PATE2 | c.113A>G p.H38R | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.833); catalogued as COSV100653420; called by muse, mutect2, varscan2
- PCDHB6 | c.1245C>A p.Y415* | Nonsense Mutation (SNP) | VAF 40/164 reads (24%) | catalogued as COSV99169884; called by muse, mutect2, varscan2
- PCDHB8 | c.2071C>A p.L691M | Missense Mutation (SNP) | VAF 73/239 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs757018919, COSV99175258; called by muse, mutect2, varscan2
- PCDHB9 | c.409G>A p.E137K | Missense Mutation (SNP) | VAF 33/130 reads (25%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.139); catalogued as COSV53378001; called by muse, mutect2, varscan2
- PGAM4 | c.34G>C p.G12R | Missense Mutation (SNP) | VAF 34/63 reads (54%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); catalogued as COSV100430130; called by muse, mutect2, varscan2
- PIEZO2 | c.7856C>T p.S2619F | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV53292003, COSV99554305; called by muse, mutect2, varscan2
- PKHD1 | c.5707G>A p.V1903I | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.017); catalogued as rs753639079, COSV61884120, COSV61891662; called by muse, mutect2, varscan2
- PLAAT5 | c.640C>A p.Q214K | Missense Mutation (SNP) | VAF 34/118 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.089); catalogued as COSV100080281; called by muse, mutect2, varscan2
- PLEKHG4B | c.741C>T p.P247= (on ENST00000283426; = p.P603= on NM_052909.5) | Splice Region (SNP) | VAF 32/103 reads (31%) | catalogued as rs377206088, COSV52054181; called by muse, mutect2, varscan2
- PLEKHG4B | c.3454G>T p.V1152L (on ENST00000283426; = p.V1508L on NM_052909.5) | Missense Mutation (SNP) | VAF 54/149 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV99359607; called by muse, mutect2, varscan2
- PNLIP | c.733C>A p.P245T | Missense Mutation (SNP) | VAF 21/132 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100981593, COSV65040597, COSV65041391; called by muse, mutect2, varscan2
- PNLIP | c.734C>G p.P245R | Missense Mutation (SNP) | VAF 21/134 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1295776120, COSV100981595, COSV100981870; called by muse, mutect2, varscan2
- PON1 | c.622T>A p.Y208N | Missense Mutation (SNP) | VAF 15/109 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99731884; called by muse, mutect2, varscan2
- PRB3 | c.247C>T p.P83S | Missense Mutation (SNP) | VAF 162/625 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.197); catalogued as COSV54393414; called by muse, mutect2, varscan2
- PREP | c.685A>T p.N229Y (on ENST00000369110; = p.N295Y on NM_002726.5) | Missense Mutation (SNP) | VAF 37/153 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100963661; called by muse, mutect2, varscan2
- PRIM1 | c.891G>T p.M297I | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.03); catalogued as COSV100590315; called by muse, mutect2, varscan2
- PRLR | c.1150G>T p.E384* | Nonsense Mutation (SNP) | VAF 28/103 reads (27%) | catalogued as COSV51495455, COSV99184192; called by muse, mutect2, varscan2
- PROSER1 | c.416G>T p.C139F | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV100612606; called by muse, mutect2, varscan2
- PTPRC | c.3461C>A p.S1154Y | Missense Mutation (SNP) | VAF 45/82 reads (55%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as COSV100722014; called by muse, mutect2, varscan2
- PTPRD | c.5298C>G p.Y1766* | Nonsense Mutation (SNP) | VAF 20/52 reads (38%) | catalogued as COSV100642686; called by muse, mutect2, varscan2
- PTPRO | c.9C>G p.H3Q | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.021); catalogued as rs769779448, COSV99839413; called by muse, varscan2
- RAB3GAP2 | c.1117C>T p.P373S | Missense Mutation (SNP) | VAF 90/174 reads (52%) | SIFT tolerated (0.07); PolyPhen benign (0.31); catalogued as COSV99424342; called by muse, mutect2, varscan2
- RADIL | c.1965G>T p.R655S | Missense Mutation (SNP) | VAF 12/122 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); catalogued as COSV101112279; called by muse, mutect2
- RB1 | c.1696-2A>G p.X566_splice | Splice Site (SNP) | VAF 14/36 reads (39%) | catalogued as CS143246, COSV57305513, COSV57309945; called by muse, mutect2, varscan2
- RCBTB1 | c.610G>A p.G204S | Missense Mutation (SNP) | VAF 8/8 reads (100%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.491); catalogued as COSV99319240; called by muse, mutect2, varscan2
- REG1B | c.41T>A p.L14Q | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs751095254, COSV100521233; called by muse, mutect2, varscan2
- RELN | c.6913C>T p.P2305S | Missense Mutation (SNP) | VAF 69/134 reads (51%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.853); catalogued as rs746934935, COSV100632034; called by muse, mutect2, varscan2
- RGS6 | c.1391G>T p.R464L | Missense Mutation (SNP) | VAF 37/80 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV100664715, COSV59579508; called by muse, mutect2, varscan2
- RNF121 | c.974del p.G325Afs*76 | Frame Shift Del (DEL) | VAF 5/51 reads (10%) | catalogued as COSV99474727; called by mutect2, varscan2
- ROPN1L | c.377G>T p.W126L | Missense Mutation (SNP) | VAF 29/120 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV99928508; called by muse, mutect2, varscan2
- ROPN1L | c.378G>T p.W126C | Missense Mutation (SNP) | VAF 29/120 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs539771885, COSV56873078, COSV56874992, COSV99928511; called by muse, mutect2, varscan2
- RPS6KA6 | c.1519G>T p.D507Y | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99423946; called by muse, mutect2, varscan2
- RTN1 | c.910C>G p.Q304E | Missense Mutation (SNP) | VAF 40/78 reads (51%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as COSV50743290; called by muse, mutect2, varscan2
- RUNX1T1 | c.395C>A p.T132N (on ENST00000265814 / NM_001198628.1; = p.T105N on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 71/133 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV56158267, COSV99748742; called by muse, mutect2, varscan2
- RYR2 | c.5588C>T p.T1863M | Missense Mutation (SNP) | VAF 47/106 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.022); catalogued as rs770863319, COSV63724318; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SAGE1 | c.413T>C p.M138T | Missense Mutation (SNP) | VAF 51/88 reads (58%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.974); catalogued as COSV100186516; called by muse, mutect2, varscan2
- SAMD9 | c.125A>G p.N42S | Missense Mutation (SNP) | VAF 11/143 reads (8%) | SIFT tolerated (0.65); PolyPhen benign (0.012); catalogued as COSV101180111; called by muse, mutect2
- SARDH | c.169C>A p.Q57K | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV100060375; called by muse, mutect2, varscan2
- SCGB3A2 | c.75C>A p.N25K | Missense Mutation (SNP) | VAF 44/163 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.037); catalogued as COSV99692579; called by muse, mutect2, varscan2
- SCN2A | c.3065G>T p.R1022L | Missense Mutation (SNP) | VAF 33/123 reads (27%) | SIFT tolerated (0.71); PolyPhen benign (0.341); catalogued as COSV99329788; called by muse, mutect2, varscan2
- SEC23A | c.1354A>G p.S452G | Missense Mutation (SNP) | VAF 21/38 reads (55%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV100304983; called by muse, mutect2, varscan2
- SELENOI | c.1009G>T p.G337* | Nonsense Mutation (SNP) | VAF 27/105 reads (26%) | catalogued as COSV99564104; called by muse, mutect2, varscan2
- SEMA3G | c.2017G>T p.V673L | Missense Mutation (SNP) | VAF 49/99 reads (49%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.927); catalogued as COSV99201831; called by muse, mutect2, varscan2
- SENP2 | c.149C>G p.P50R | Missense Mutation (SNP) | VAF 11/114 reads (10%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.996); catalogued as COSV99957474; called by muse, mutect2, varscan2
- SENP5 | c.2077C>T p.L693F | Missense Mutation (SNP) | VAF 11/127 reads (9%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); catalogued as COSV60209042; called by muse, mutect2
- SERPINI1 | c.572A>T p.K191M | Missense Mutation (SNP) | VAF 27/219 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99854773; called by muse, mutect2, varscan2
- SI | c.2975C>A p.S992Y | Missense Mutation (SNP) | VAF 14/175 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.71); catalogued as COSV100013549; called by muse, mutect2
- SKIL | c.761A>G p.Q254R | Missense Mutation (SNP) | VAF 36/225 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as rs1194688041, COSV99377977; called by muse, mutect2, varscan2
- SLC12A2 | c.2185G>A p.V729I | Missense Mutation (SNP) | VAF 36/82 reads (44%) | SIFT tolerated (0.34); PolyPhen benign (0.131); catalogued as rs575733487, COSV52471986; called by muse, mutect2, varscan2
- SLC17A6 | c.647C>A p.T216N | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99580523; called by muse, mutect2, varscan2
- SLC26A4 | c.443T>G p.V148G | Missense Mutation (SNP) | VAF 17/138 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99706473; called by muse, mutect2, varscan2
- SLC26A9 | c.922C>G p.H308D | Missense Mutation (SNP) | VAF 21/140 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as COSV100535911, COSV61602794; called by muse, mutect2, varscan2
- SLC8A1 | c.2000G>C p.R667T | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT tolerated (0.25); PolyPhen benign (0.024); catalogued as rs148383040, COSV60487097; called by muse, mutect2, varscan2
- SLCO1C1 | c.404+1G>T p.X135_splice | Splice Site (SNP) | VAF 68/253 reads (27%) | catalogued as COSV99858295; called by muse, mutect2, varscan2
- SLCO2A1 | c.1235G>T p.C412F | Missense Mutation (SNP) | VAF 25/99 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.227); catalogued as COSV100188598; called by muse, mutect2, varscan2
- SMG6 | c.4189G>T p.V1397L | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT tolerated (0.21); PolyPhen benign (0.132); catalogued as COSV99557647; called by muse, mutect2, varscan2
- SMYD3 | c.1264G>A p.D422N (on ENST00000490107 / NM_001375962.1; = p.D363N on NM_022743.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.038); catalogued as rs767335863, COSV63625877; called by muse, mutect2, varscan2
- SORBS2 | c.3257C>A p.T1086N (on ENST00000284776 / NM_021069.5; = p.T652N on NM_003603.6) | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99509257; called by muse, mutect2, varscan2
- SORCS3 | c.1150C>A p.P384T | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV63803269, COSV63816852; called by muse, mutect2, varscan2
- SPIDR | c.2709C>G p.I903M | Missense Mutation (SNP) | VAF 18/141 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV52373101, COSV99854022; called by muse, mutect2, varscan2
- SPPL2B | c.1475G>T p.R492L | Missense Mutation (SNP) | VAF 32/137 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101476094; called by muse, mutect2, varscan2
- SPTA1 | c.6183G>T p.K2061N | Missense Mutation (SNP) | VAF 45/101 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100934070, COSV100934404, COSV63758126; called by muse, mutect2, varscan2
- SRPX | c.487G>T p.D163Y | Missense Mutation (SNP) | VAF 37/62 reads (60%) | SIFT tolerated (0.29); PolyPhen benign (0.077); catalogued as COSV100655855; called by muse, mutect2, varscan2
- ST18 | c.1159C>A p.R387S | Missense Mutation (SNP) | VAF 66/135 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.7); catalogued as COSV99387837, COSV99390232; called by muse, mutect2, varscan2
- TAGAP | c.1730C>A p.S577* | Nonsense Mutation (SNP) | VAF 37/157 reads (24%) | catalogued as COSV100487231; called by muse, mutect2, varscan2
- TBC1D8 | c.1334G>T p.S445I | Missense Mutation (SNP) | VAF 39/126 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.299); catalogued as COSV100964229; called by muse, mutect2, varscan2
- TBX22 | c.1090C>A p.L364M | Missense Mutation (SNP) | VAF 57/85 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as COSV100960563; called by muse, mutect2, varscan2
- TCF25 | c.233G>T p.G78V | Missense Mutation (SNP) | VAF 28/99 reads (28%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.52); catalogued as COSV99642213; called by muse, mutect2, varscan2
- TIAM2 | c.4333T>G p.W1445G (on ENST00000529824; = p.W1416G on NM_012454.3) | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99264950; called by muse, mutect2, varscan2
- TMEM244 | c.79G>A p.V27M | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.045); catalogued as COSV100933515; called by muse, mutect2, varscan2
- TMPRSS12 | c.541G>C p.V181L | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as COSV101269065; called by muse, varscan2
- TP53 | c.520A>T p.R174W | Missense Mutation (SNP) | VAF 32/69 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as CM942119, COSV52688040, COSV52961532, COSV53198425; called by muse, mutect2, varscan2
- TP63 | c.1663A>T p.R555W | Missense Mutation (SNP) | VAF 20/121 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV99285123; called by muse, mutect2, varscan2
- TPR | c.3158G>A p.R1053K | Missense Mutation (SNP) | VAF 77/168 reads (46%) | SIFT tolerated (0.29); PolyPhen benign (0.145); catalogued as rs781044687, COSV100823563; called by muse, mutect2, varscan2
- TRIM27 | c.607C>T p.R203C | Missense Mutation (SNP) | VAF 70/228 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs781445616, COSV101019191; called by muse, mutect2, varscan2
- TRIM49 | c.140C>A p.P47Q | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT tolerated (0.7); PolyPhen benign (0.06); catalogued as rs1389874687, COSV100315852; called by muse, mutect2, varscan2
- TSPAN11 | c.184T>A p.Y62N | Missense Mutation (SNP) | VAF 111/371 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV99666522; called by muse, mutect2, varscan2
- TTLL11 | c.44C>A p.A15D | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.017); catalogued as COSV100388327; called by muse, varscan2
- USH2A | c.8453C>A p.P2818H | Missense Mutation (SNP) | VAF 104/199 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.042); catalogued as COSV100227918, COSV56441655; called by muse, mutect2, varscan2
- USP9Y | c.1791A>G p.I597M | Missense Mutation (SNP) | VAF 27/45 reads (60%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as COSV100168154; called by muse, mutect2, varscan2
- VCPIP1 | c.2883G>T p.L961F | Missense Mutation (SNP) | VAF 18/151 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100125277; called by muse, mutect2, varscan2
- WFS1 | c.2649del p.F884Sfs*68 | Frame Shift Del (DEL) | VAF 19/72 reads (26%) | catalogued as rs71524394, CD053622, COSV99901247; called by mutect2, pindel, varscan2
- WNT9A | c.389C>G p.S130W | Missense Mutation (SNP) | VAF 48/140 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55295083, COSV99687964; called by muse, mutect2, varscan2
- WRN | c.5G>T p.S2I | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.023); catalogued as COSV99988138; called by muse, mutect2, varscan2
- XIRP2 | c.2019G>T p.Q673H (on ENST00000628543; = p.Q848H on NM_152381.6) | Missense Mutation (SNP) | VAF 54/166 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.046); catalogued as COSV99737378; called by muse, mutect2
- ZBP1 | c.296A>G p.E99G | Missense Mutation (SNP) | VAF 54/144 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs1324690301, COSV100472920; called by muse, mutect2, varscan2
- ZBTB46 | c.941C>A p.A314E | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT tolerated (0.37); PolyPhen benign (0.012); catalogued as COSV55507899, COSV99828655; called by muse, mutect2, varscan2
- ZFHX4 | c.1084G>T p.G362C | Missense Mutation (SNP) | VAF 13/120 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); catalogued as COSV50656469, COSV50871021; called by muse, mutect2, varscan2
- ZNF146 | c.34G>T p.G12W | Missense Mutation (SNP) | VAF 36/213 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV100757610; called by muse, mutect2, varscan2
- ZNF181 | c.1250T>A p.L417H | Missense Mutation (SNP) | VAF 50/243 reads (21%) | SIFT tolerated (0.54); PolyPhen benign (0.133); catalogued as COSV101106155; called by muse, mutect2, varscan2
- ZNF189 | c.871A>T p.T291S | Missense Mutation (SNP) | VAF 71/271 reads (26%) | SIFT tolerated (0.48); PolyPhen benign (0.103); catalogued as COSV99407061; called by muse, mutect2, varscan2
- ZNF257 | c.233G>A p.C78Y | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV101447991, COSV71311176; called by muse, mutect2, varscan2
- ZNF398 | c.1394G>T p.S465I (on ENST00000475153 / NM_170686.3; = p.S294I on NM_020781.4) | Missense Mutation (SNP) | VAF 74/133 reads (56%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.594); catalogued as COSV100246788; called by muse, mutect2, varscan2
- ZNF423 | c.2116G>A p.D706N (on ENST00000563137 / NM_001379286.1; = p.D698N on NM_015069.4) | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.205); catalogued as rs148732968; called by muse, mutect2, varscan2
- ZNF471 | c.440T>C p.I147T | Missense Mutation (SNP) | VAF 18/29 reads (62%) | SIFT tolerated (0.26); PolyPhen benign (0.026); catalogued as COSV100340301; called by muse, mutect2, varscan2
- ZNF582 | c.1418A>G p.H473R | Missense Mutation (SNP) | VAF 62/129 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs774405206, COSV100018450; called by muse, mutect2, varscan2
- ZNF624 | c.1339A>T p.N447Y | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.132); catalogued as COSV100256947; called by muse, mutect2, varscan2
- ZNF800 | c.1607G>A p.R536Q | Missense Mutation (SNP) | VAF 67/124 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV56173920, COSV56179212; called by muse, mutect2, varscan2
- ZNRF4 | c.1219T>A p.C407S | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.014); catalogued as COSV99706295; called by muse, mutect2, varscan2
- CFAP44 | c.1056_1066del p.I353Afs*15 | Frame Shift Del (DEL) | VAF 38/275 reads (14%) | called by mutect2, pindel, varscan2
- CHAF1A | c.2765C>T p.A922V | Missense Mutation (SNP) | VAF 2/8 reads (25%) | SIFT tolerated (0.72); PolyPhen benign (0.051); called by muse, mutect2
- CSMD2 | c.8507del p.G2836Vfs*21 | Frame Shift Del (DEL) | VAF 8/43 reads (19%) | called by mutect2, pindel, varscan2
- DCC | c.3257del p.P1086Rfs*15 | Frame Shift Del (DEL) | VAF 19/84 reads (23%) | called by mutect2, pindel, varscan2
- FRG2C | c.32A>T p.H11L | Missense Mutation (SNP) | VAF 32/140 reads (23%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.923); called by muse, mutect2
- HECTD4 | c.12416del p.L4139Rfs*75 | Frame Shift Del (DEL) | VAF 26/114 reads (23%) | called by pindel, varscan2
- KRTAP5-10 | c.305_306insAGGCTGTGGCTCCTATGGGGGCTCCAAGGG p.S106_C107insYGGSKGGCGS | In Frame Ins (INS) | VAF 22/200 reads (11%) | called by muse*, mutect2, varscan2*
- MRC1 | c.1749G>T p.E583D | Missense Mutation (SNP) | VAF 41/176 reads (23%) | SIFT tolerated (0.44); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- OR12D2 | c.854dup p.N285Kfs*18 | Frame Shift Ins (INS) | VAF 51/161 reads (32%) | called by mutect2, pindel, varscan2
- PIK3CA | c.2348G>T p.W783L | Missense Mutation (SNP) | VAF 25/214 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- SMIM29 | c.236dup p.D79Efs*7 (on ENST00000394990 / NM_001008704.3; = p.D99Efs*7 on NM_178508.5) | Frame Shift Ins (INS) | VAF 20/74 reads (27%) | called by mutect2, pindel, varscan2
- TBCE | c.342del p.I114Mfs*7 | Frame Shift Del (DEL) | VAF 55/128 reads (43%) | called by mutect2, pindel, varscan2
- THSD7A | c.3036del p.V1013Wfs*43 | Frame Shift Del (DEL) | VAF 106/276 reads (38%) | called by mutect2, pindel, varscan2
- TP53BP2 | c.2704G>T p.G902W (on ENST00000343537 / NM_001031685.3; = p.G773W on NM_005426.2) | Missense Mutation (SNP) | VAF 26/182 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TPTE | c.1612G>A p.G538S (on ENST00000618007 / NM_199261.4; = p.G520S on NM_199259.4) | Missense Mutation (SNP) | VAF 4/90 reads (4%) | SIFT tolerated (0.72); PolyPhen benign (0.05); called by muse, mutect2
- TPTE | c.1613G>T p.G538V (on ENST00000618007 / NM_199261.4; = p.G520V on NM_199259.4) | Missense Mutation (SNP) | VAF 4/92 reads (4%) | SIFT tolerated (0.13); PolyPhen benign (0.407); called by muse, mutect2
- VN1R5 | c.568C>A p.P190T | Missense Mutation (SNP) | VAF 79/438 reads (18%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.639); called by muse, mutect2, varscan2
- ABCC9 | c.1971A>G p.Q657= | Silent (SNP) | VAF 18/92 reads (20%) | catalogued as COSV99684125; called by muse, mutect2, varscan2
- ACAD9 | c.1614C>T p.I538= | Silent (SNP) | VAF 9/55 reads (16%) | catalogued as rs202183844, COSV100458884; called by muse, mutect2, varscan2
- ACSM5 | c.894C>A p.P298= | Silent (SNP) | VAF 22/63 reads (35%) | catalogued as COSV59371428, COSV59375331; called by muse, mutect2, varscan2
- ADD2 | c.339G>A p.T113= | Silent (SNP) | VAF 10/46 reads (22%) | catalogued as rs370078692; called by muse, mutect2, varscan2
- AGO1 | c.1239G>C p.A413= | Silent (SNP) | VAF 39/125 reads (31%) | catalogued as COSV100940732; called by muse, mutect2, varscan2
- AP3S2 | c.396A>C p.T132= | Silent (SNP) | VAF 42/94 reads (45%) | catalogued as COSV100318340; called by muse, mutect2, varscan2
- ARHGAP29 | c.3276C>A p.A1092= | Silent (SNP) | VAF 59/226 reads (26%) | catalogued as COSV99557453; called by muse, mutect2, varscan2
- ATP1A2 | c.741T>C p.C247= | Silent (SNP) | VAF 14/68 reads (21%) | catalogued as rs371882060; ClinVar: likely benign; called by muse, mutect2, varscan2
- BACE2 | c.1227C>T p.A409= | Silent (SNP) | VAF 15/68 reads (22%) | catalogued as rs1232031468, COSV100160438; called by muse, mutect2, varscan2
- C6orf118 | c.792C>T p.F264= | Silent (SNP) | VAF 87/311 reads (28%) | catalogued as COSV100023954; called by muse, mutect2, varscan2
- CACNA1G | c.6915A>G p.K2305= | Silent (SNP) | VAF 10/26 reads (38%) | catalogued as COSV100661026; called by muse, mutect2, varscan2
- CC2D1B | c.718A>C p.R240= | Silent (SNP) | VAF 26/74 reads (35%) | catalogued as COSV99429608; called by muse, mutect2, varscan2
- CD96 | c.1683A>T p.P561= (on ENST00000283285 / NM_198196.3; = p.P545= on NM_005816.5) | Silent (SNP) | VAF 58/292 reads (20%) | catalogued as COSV99342187; called by muse, mutect2, varscan2
- CDK5R2 | c.216G>T p.A72= | Silent (SNP) | VAF 8/23 reads (35%) | catalogued as COSV100225827; called by muse, mutect2, varscan2
- CNTNAP1 | c.1998C>A p.S666= | Silent (SNP) | VAF 84/317 reads (26%) | catalogued as COSV99226051; called by muse, mutect2, varscan2
- COL4A1 | c.4389G>T p.G1463= | Silent (SNP) | VAF 330/504 reads (65%) | catalogued as COSV101010915; called by muse, varscan2
- COL6A6 | c.1053A>G p.A351= | Silent (SNP) | VAF 80/348 reads (23%) | catalogued as COSV100649678; called by muse, mutect2, varscan2
- COPA | c.1092A>T p.P364= | Silent (SNP) | VAF 63/140 reads (45%) | catalogued as COSV99614364; called by muse, mutect2, varscan2
- COPA | c.915C>G p.L305= | Silent (SNP) | VAF 28/106 reads (26%) | catalogued as COSV99614367; called by muse, mutect2, varscan2
- CSMD3 | c.3660C>A p.I1220= (on ENST00000297405 / NM_001363185.1; = p.I1116= on NM_052900.3) | Silent (SNP) | VAF 17/130 reads (13%) | catalogued as rs1434462941, COSV52091934, COSV52149804; called by muse, mutect2, varscan2
- CUBN | c.6222C>A p.T2074= | Silent (SNP) | VAF 14/89 reads (16%) | catalogued as COSV100911934; called by muse, mutect2, varscan2
- CYB5R4 | c.1386A>G p.E462= | Silent (SNP) | VAF 30/95 reads (32%) | catalogued as COSV100859623; called by muse, mutect2, varscan2
- CYP27A1 | c.1005T>C p.A335= | Silent (SNP) | VAF 17/76 reads (22%) | catalogued as rs776938750, COSV99298281; called by muse, mutect2, varscan2
- CYP4B1 | c.1308C>T p.S436= | Silent (SNP) | VAF 40/125 reads (32%) | catalogued as rs555691883, COSV99596689; called by muse, mutect2, varscan2
- DLGAP2 | c.949C>A p.R317= | Silent (SNP) | VAF 26/198 reads (13%) | catalogued as COSV101420983, COSV70097856; called by muse, mutect2, varscan2
- DNAH5 | c.3570C>A p.V1190= | Silent (SNP) | VAF 27/90 reads (30%) | catalogued as COSV99443820; called by muse, mutect2, varscan2
- DYRK4 | c.1446G>T p.L482= | Silent (SNP) | VAF 29/104 reads (28%) | catalogued as COSV50539047, COSV99155260; called by muse, mutect2, varscan2
- ELOA | c.1314C>T p.S438= | Silent (SNP) | VAF 91/327 reads (28%) | catalogued as COSV101403575; called by muse, mutect2, varscan2
- FAH | c.822G>T p.V274= | Silent (SNP) | VAF 53/148 reads (36%) | catalogued as COSV99929973; called by muse, mutect2, varscan2
- FAM114A1 | c.870G>A p.G290= | Silent (SNP) | VAF 15/55 reads (27%) | catalogued as COSV100729115; called by muse, mutect2, varscan2
- FBXL7 | c.141C>T p.S47= | Silent (SNP) | VAF 37/148 reads (25%) | catalogued as COSV100308850; called by muse, mutect2, varscan2
- FCGBP | c.7950C>A p.P2650= | Silent (SNP) | VAF 32/225 reads (14%) | called by muse, mutect2
- FRG2C | c.30C>T p.L10= | Silent (SNP) | VAF 31/141 reads (22%) | called by muse, mutect2
- FSTL5 | c.948T>C p.V316= | Silent (SNP) | VAF 17/55 reads (31%) | catalogued as COSV100051873; called by muse, mutect2, varscan2
- GJA9 | c.432A>T p.L144= | Silent (SNP) | VAF 43/168 reads (26%) | catalogued as COSV100668025; called by muse, mutect2, varscan2
- GLP2R | c.162T>A p.T54= | Silent (SNP) | VAF 5/31 reads (16%) | catalogued as COSV99301453; called by muse, mutect2, varscan2
- GOLT1A | c.390G>A p.S130= | Silent (SNP) | VAF 23/130 reads (18%) | catalogued as rs1296275353, COSV100383406; called by muse, mutect2, varscan2
- GRB14 | c.354C>G p.T118= | Silent (SNP) | VAF 24/59 reads (41%) | catalogued as COSV99813561; called by muse, mutect2, varscan2
- GTF3C1 | c.1317A>T p.L439= | Silent (SNP) | VAF 92/169 reads (54%) | catalogued as COSV100648875; called by muse, mutect2, varscan2
- HAO2 | c.165G>T p.V55= | Silent (SNP) | VAF 19/42 reads (45%) | catalogued as COSV100377704; called by muse, mutect2, varscan2
- HMCN1 | c.12132G>A p.Q4044= | Silent (SNP) | VAF 23/120 reads (19%) | catalogued as COSV54877529, COSV54923258, COSV99622951; called by muse, mutect2, varscan2
- HOXD3 | c.381C>A p.P127= | Silent (SNP) | VAF 12/88 reads (14%) | catalogued as COSV99979833; called by muse, mutect2, varscan2
- HOXD9 | c.828C>T p.A276= | Silent (SNP) | VAF 29/104 reads (28%) | catalogued as rs764657611, COSV99981659; called by muse, mutect2, varscan2
- HYAL2 | c.1215C>T p.P405= | Silent (SNP) | VAF 8/125 reads (6%) | catalogued as COSV100753805; called by muse, mutect2
- HYAL4 | c.1179C>T p.N393= | Silent (SNP) | VAF 61/136 reads (45%) | catalogued as rs758539563, COSV56139184; called by muse, mutect2, varscan2
- INTS1 | c.1536C>T p.F512= | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as COSV101247327; called by muse, mutect2, varscan2
- JUN | c.228G>T p.L76= | Silent (SNP) | VAF 108/291 reads (37%) | catalogued as COSV100973359; called by muse, mutect2, varscan2
- LYST | c.11259C>T p.P3753= | Silent (SNP) | VAF 12/218 reads (6%) | catalogued as COSV101087844; called by muse, mutect2
- MACC1 | c.4C>T p.L2= | Silent (SNP) | VAF 44/96 reads (46%) | catalogued as rs553622073, COSV100255213; called by muse, mutect2, varscan2
- MCAM | c.357G>A p.K119= | Silent (SNP) | VAF 37/90 reads (41%) | catalogued as COSV99877487; called by muse, mutect2, varscan2
- MED12L | c.6111A>T p.P2037= | Silent (SNP) | VAF 68/147 reads (46%) | catalogued as COSV99851143; called by muse, mutect2, varscan2
- METTL15 | c.654A>T p.A218= | Silent (SNP) | VAF 21/85 reads (25%) | catalogued as COSV100327753; called by muse, mutect2, varscan2
- MGAT4A | c.1542A>C p.S514= | Silent (SNP) | VAF 19/70 reads (27%) | catalogued as COSV99383867; called by muse, mutect2, varscan2
- MUC16 | c.19215C>T p.S6405= | Silent (SNP) | VAF 39/139 reads (28%) | catalogued as COSV101197496; called by muse, mutect2, varscan2
- MUC4 | c.1314C>G p.L438= | Silent (SNP) | VAF 102/686 reads (15%) | catalogued as COSV100638826; called by muse, mutect2, varscan2
- NLRP2 | c.354A>G p.L118= | Silent (SNP) | VAF 50/97 reads (52%) | catalogued as COSV99671763; called by muse, mutect2, varscan2
- NLRP2 | c.1659A>G p.A553= | Silent (SNP) | VAF 32/82 reads (39%) | catalogued as rs777063704, COSV99671766; called by muse, mutect2, varscan2
- OBSCN | c.2442G>A p.P814= | Silent (SNP) | VAF 84/149 reads (56%) | catalogued as rs571107310, COSV99471227; called by muse, mutect2, varscan2
- OR11H6 | c.888C>T p.Y296= | Silent (SNP) | VAF 32/145 reads (22%) | catalogued as COSV100209685; called by muse, mutect2, varscan2
- OR7A10 | c.117G>A p.V39= | Silent (SNP) | VAF 41/117 reads (35%) | catalogued as COSV99932345; called by muse, mutect2, varscan2
- PANX3 | c.435C>T p.S145= | Silent (SNP) | VAF 18/51 reads (35%) | catalogued as rs201186259; called by muse, mutect2, varscan2
- PATJ | c.4470G>T p.G1490= | Silent (SNP) | VAF 20/73 reads (27%) | catalogued as COSV100332905; called by muse, mutect2, varscan2
- POSTN | c.1920G>T p.L640= | Silent (SNP) | VAF 9/21 reads (43%) | catalogued as COSV101123227; called by muse, mutect2, varscan2
- POTEE | c.2121G>T p.V707= | Silent (SNP) | VAF 4/13 reads (31%) | called by mutect2, varscan2
- PPP4R1 | c.1185A>T p.L395= (on ENST00000400556 / NM_001042388.3; = p.L378= on NM_005134.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 33/90 reads (37%) | catalogued as COSV99553033; called by muse, mutect2, varscan2
- PRC1 | c.462C>T p.N154= | Silent (SNP) | VAF 10/75 reads (13%) | catalogued as COSV100727011; called by muse, mutect2, varscan2
- PRDM1 | c.966G>T p.T322= | Silent (SNP) | VAF 58/201 reads (29%) | catalogued as COSV100958496; called by muse, mutect2, varscan2
- PRDM10 | c.2712A>G p.T904= | Silent (SNP) | VAF 147/334 reads (44%) | catalogued as COSV100456526; called by muse, mutect2, varscan2
- PROSER1 | c.1533T>A p.S511= | Silent (SNP) | VAF 29/71 reads (41%) | catalogued as COSV100612603; called by muse, mutect2, varscan2
- PRSS35 | c.342G>A p.K114= | Silent (SNP) | VAF 27/100 reads (27%) | catalogued as COSV100864009; called by muse, mutect2, varscan2
- QRFPR | c.1122A>G p.A374= | Silent (SNP) | VAF 46/139 reads (33%) | catalogued as COSV100543405; called by muse, mutect2, varscan2
- RELL2 | c.147G>C p.S49= | Silent (SNP) | VAF 36/154 reads (23%) | catalogued as COSV51837023, COSV51838749; called by muse, mutect2, varscan2
- ROBO1 | c.3228T>C p.T1076= | Silent (SNP) | VAF 70/124 reads (56%) | catalogued as COSV101458239; called by muse, mutect2, varscan2
- RP1L1 | c.2376G>A p.L792= | Silent (SNP) | VAF 25/166 reads (15%) | catalogued as rs753353955, COSV101222876, COSV101223346; called by muse, mutect2, varscan2
- RSU1 | c.276C>T p.N92= | Silent (SNP) | VAF 35/229 reads (15%) | catalogued as COSV100590117; called by muse, mutect2, varscan2
- SOAT2 | c.840C>T p.L280= | Silent (SNP) | VAF 39/153 reads (25%) | catalogued as rs746542778, COSV100037324; called by muse, mutect2, varscan2
- SPATA18 | c.1578G>A p.R526= | Silent (SNP) | VAF 10/100 reads (10%) | catalogued as COSV99729800; called by muse, mutect2, varscan2
- SPATA31A6 | c.2076G>T p.V692= | Silent (SNP) | VAF 20/48 reads (42%) | catalogued as rs1371810943, COSV100252914; called by mutect2, varscan2
- SPEG | c.888C>T p.R296= | Silent (SNP) | VAF 20/57 reads (35%) | catalogued as COSV100403052; called by muse, mutect2, varscan2
- SPTBN1 | c.4935A>G p.A1645= | Silent (SNP) | VAF 43/146 reads (29%) | catalogued as rs145221949; called by muse, mutect2, varscan2
- TAF2 | c.3105C>T p.N1035= | Silent (SNP) | VAF 25/224 reads (11%) | catalogued as COSV100978349; called by muse, mutect2, varscan2
- THSD7A | c.564C>T p.L188= | Silent (SNP) | VAF 27/75 reads (36%) | catalogued as COSV101448508, COSV101448892; called by muse, mutect2, varscan2
- TIMM44 | c.972C>T p.I324= | Silent (SNP) | VAF 34/150 reads (23%) | catalogued as COSV54491461; called by muse, mutect2, varscan2
- TMEM184A | c.174C>G p.V58= | Silent (SNP) | VAF 69/116 reads (59%) | catalogued as COSV99867704; called by muse, mutect2, varscan2
- TMTC2 | c.166C>T p.L56= | Silent (SNP) | VAF 41/171 reads (24%) | catalogued as COSV100337483; called by muse, mutect2, varscan2
- TPCN2 | c.660G>A p.G220= | Silent (SNP) | VAF 13/55 reads (24%) | catalogued as COSV99593104; called by muse, mutect2, varscan2
- TTN | c.74865C>T p.S24955= (on ENST00000591111; = p.S17531= on NM_003319.4) | Silent (SNP) | VAF 55/206 reads (27%) | catalogued as rs777989882, COSV60086879; ClinVar: likely benign; called by muse, mutect2, varscan2
- TTN | c.39246G>A p.K13082= (on ENST00000591111; = p.K5658= on NM_003319.4) | Silent (SNP) | VAF 9/27 reads (33%) | catalogued as COSV100590638; called by muse, mutect2, varscan2
- UBC | c.534C>G p.V178= | Silent (SNP) | VAF 61/273 reads (22%) | catalogued as COSV100298757; called by muse, mutect2, varscan2
- UBE2G2 | c.207A>T p.P69= | Silent (SNP) | VAF 21/88 reads (24%) | catalogued as COSV100446017; called by muse, mutect2, varscan2
- USH2A | c.11094G>A p.V3698= | Silent (SNP) | VAF 63/158 reads (40%) | catalogued as COSV100227915; called by muse, mutect2, varscan2
- USH2A | c.3471C>T p.I1157= | Silent (SNP) | VAF 97/215 reads (45%) | catalogued as COSV100227919; called by muse, mutect2, varscan2
- VAT1L | c.297C>A p.P99= | Silent (SNP) | VAF 47/136 reads (35%) | catalogued as COSV100212803; called by muse, mutect2, varscan2
- VGLL4 | c.708C>T p.S236= | Silent (SNP) | VAF 58/129 reads (45%) | catalogued as rs780751208, COSV99809073; called by muse, mutect2, varscan2
- ZBTB7B | c.1492C>T p.L498= (on ENST00000292176; = p.L532= on NM_001252406.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 27/76 reads (36%) | catalogued as COSV99420703; called by muse, mutect2, varscan2
- ZEB1 | c.2220A>G p.P740= | Silent (SNP) | VAF 12/82 reads (15%) | catalogued as COSV100313503; called by muse, mutect2, varscan2
- ZFAT | c.2130A>T p.S710= | Silent (SNP) | VAF 114/182 reads (63%) | catalogued as COSV100914124; called by muse, mutect2, varscan2
- ZNF14 | c.1167A>G p.K389= | Silent (SNP) | VAF 36/118 reads (31%) | catalogued as COSV100693947; called by muse, mutect2, varscan2
- ZNF536 | c.1278G>T p.L426= | Silent (SNP) | VAF 59/265 reads (22%) | catalogued as COSV100834514; called by muse, mutect2, varscan2
- ZNF658 | c.591T>C p.A197= | Silent (SNP) | VAF 10/38 reads (26%) | called by muse, mutect2, varscan2
- ZNF777 | c.1827C>T p.P609= | Silent (SNP) | VAF 139/262 reads (53%) | catalogued as COSV99924931; called by muse, mutect2, varscan2
- ZSCAN4 | c.78A>G p.Q26= | Silent (SNP) | VAF 32/63 reads (51%) | catalogued as COSV58999148; called by muse, mutect2, varscan2
- AC244258.1 | n.784T>C | RNA (SNP) | VAF 7/34 reads (21%) | catalogued as rs771545390; called by muse, mutect2
- AL353804.4 | chrX:73823012 A>G | 5'Flank (SNP) | VAF 16/64 reads (25%) | called by muse, mutect2, varscan2
- AL353804.7 | chrX:73845518 G>A | 5'Flank (SNP) | VAF 46/75 reads (61%) | catalogued as rs1422227931; called by muse, mutect2, varscan2
- CCDC18 | c.-3+275C>A | Intron (SNP) | VAF 20/42 reads (48%) | catalogued as COSV100159148; called by muse, mutect2, varscan2
- CR1 | c.487+12124G>C | Intron (SNP) | VAF 118/289 reads (41%) | catalogued as COSV100887327, COSV65456691; called by muse, mutect2, varscan2
- EI24P4 | n.956T>C | RNA (SNP) | VAF 44/402 reads (11%) | called by muse, mutect2, varscan2
- HERC2P3 | n.790A>G | RNA (SNP) | VAF 59/257 reads (23%) | called by muse, mutect2, varscan2
- NBPF11 | c.-548-3083G>T | Intron (SNP) | VAF 40/195 reads (21%) | called by muse, mutect2, varscan2
- SSPOP | n.8368del | RNA (DEL) | VAF 28/54 reads (52%) | called by mutect2, pindel, varscan2
- UBTFL2 | n.680C>A | RNA (SNP) | VAF 16/98 reads (16%) | called by muse, mutect2, varscan2
